Surgical pathology report (de-identified scan), TCGA case TCGA-61-1910, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1910-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: OVARY AND FALLOPIAN TUBE, LEFT SALPINGOOOPHORECTOMY -

- A. OVARY WITH POORLY DIFFERENTIATED SEROUS PAPILLARY ADENOCARCINOMA (GRADE 3), INVOLVING OVARIAN STROMA AND SEROSA, WITH EPITHELIAL INCLUSIONS (ENDOSALPINGIOSIS) AND CALCIFICATION. (see comment)
- B. FALLOPIAN TUBE WITH LUMINAL SEROUS PAPILLARY ADENOCARCINOMA. (see comment)

PART 2: UTERUS WITH RIGHT OVARY AND FALLOPIAN TUBE, TOTAL ABDOMINAL HYSTERECTOMY AND RIGHT SALPINGOOOPHORECTOMY (90 GRAMS) -

- A. CHRONIC CERVICITIS.
- B. BASAL ENDOMETRIUM.
- C. MULTIPLE LEIOMYOMAS UP TO 3.5 CM WITH HYALINIZATION AND CALCIFICATIONS.
- D. RIGHT OVARY WITH SEROUS PAPILLARY ADENOCARCINOMA FOCALLY INVOLVING SEROSA (2G), WITH EPITHELIAL INCLUSIONS (ENDOSALPINGIOSIS) AND CALCIFICATION (see comment).
- E. RIGHT FALLOPIAN TUBE WITH PARATUBAL CYST, NO TUMOR SEEN.

PART 3: SOFT TISSUE, LEFT BROAD LIGAMENT, BIOPSY -

SEROUS PAPILLARY ADENOCARCINOMA WITH LYMPHO-VASCULAR PERMEATION.

PART 4: LYMPH NODES, RIGHT PELVIC, BIOPSY -

TWELVE LYMPH NODES, FREE OF TUMOR (0/12). *

PART 5: LYMPH NODE, RIGHT PERI-AORTIC, BIOPSY -

ONE LYMPH NODE, FREE OF TUMOR (0/1).

PART 6: LYMPH NODES, LEFT PERI-AORTIC, BIOPSY -

TWO (2) LYMPH NODE, FREE OF TUMOR (0/2).

PART 7: LYMPH NODES, LEFT PELVIC, BIOPSY -

TWO LYMPH NODES, FREE OF TUMOR (0/2).

PART 8: SOFT TISSUE, RIGHT PELVIC SIDEWALL, BIOPSY -

FIBROADIPOSE TISSUE, NO TUMOR SEEN.

PART 9: SOFT TISSUE, LEFT PELVIC SIDEWALL, BIOPSY -

PART 10: OMENTUM, OMENTECTOMY -

OMENTUM, NO TUMOR SEEN.

PART 11: SOFT TISSUE, RIGHT PERICOLIC GUTTER, BIOPSY -

FIBROVASCULAR TISSUE, NO TUMOR SEEN.

PART 12: SOFT TISSUE, LEFT PERICOLIC GUTTER, BIOPSY -

FIBROADIPOSE TISSUE AND SKELETAL MUSCLE, NO TUMOR SEEN.

MICROSCOPIC:

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Bilateral
PROCEDURE:	TAH with salpingo-oophorectomy
TUMOR SIZE:	Maximum dimension: 6 cm
TUMOR TYPE:	Papillary serous carcinoma
HISTOLOGIC SILVERBERG GRADE:	Poorly differentiated (8-9 pts)
ARCHITECTURAL PATTERN:	Solid (3)
CYTOLOGIC ATYPIA:	Marked (3)
MITOTIC COUNTS / 10hpf:	10-24 (2)
VASCULAR INVASION:	Yes
TUMOR CAPSULE:	Ruptured
SURFACE IMPLANTS:	Invasive
SURFACE IMPLANT SITE:	Fallopian Tubes
SURFACE IMPLANT SIZE:	> 2 cm.
ASSOCIATED OTHER LESION:	Surface epithelial inclusion
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING:	Yes
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 17
LYMPH NODES POSITIVE:	Number of positive lymph nodes, Right: 0 Number of positive lymph nodes, Left: 0

T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
FIGO STAGE:	IIc

Source: NCI Genomic Data Commons file 16718768-684e-4bcf-af74-ee9831b0850b (TCGA-61-1910.32905714-6E41-4DF8-91DD-6D3068475B40.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).